Somatic mutation profile of tumor specimen ALCH-AEDY-TTP1-A (aliquot ALCH-AEDY-TTP1-A-1-0-D-A618-36) from ALCHEMIST case ALCH-AEDY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.6 years (18,486 days).
Specimen ALCH-AEDY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d6c6312-b982-40bd-8b42-5fc20090fb10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEDY-NB1-A (Blood Derived Normal), aliquot ALCH-AEDY-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07e8ba97-e2cd-4d54-a935-d6538f5565f6

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Splice Site 2, Intron 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 35/440 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 22/205 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 18/210 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867114783, COSV52676197, COSV52682212, COSV52698349, COSV52762255; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ARID2 | c.3679C>T p.Q1227* | Nonsense Mutation (SNP) | VAF 12/241 reads (5%) | catalogued as rs1213601057; called by muse, mutect2
- CYP2A6 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 29/343 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1488959980, COSV56534449; called by muse, mutect2
- EEF2K | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs189363550; called by muse, mutect2, varscan2
- FLG | c.3274G>C p.D1092H | Missense Mutation (SNP) | VAF 25/494 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV64244191; called by muse, mutect2
- HNRNPA2B1 | c.277C>A p.P93T (on ENST00000354667 / NM_031243.3; = p.P81T on NM_002137.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV61161383; called by muse, mutect2, varscan2
- PLCD4 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101335820; called by mutect2, varscan2
- TOX2 | c.1121C>T p.P374L (on ENST00000358131 / NM_001098798.2; = p.P350L on NM_032883.3) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs748284007; called by muse, mutect2, varscan2
- TRIM51 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761464608, COSV99792079; called by muse, mutect2
- VPS13B | c.2384A>G p.N795S | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs376115412; called by muse, mutect2, varscan2
- ANXA5 | c.396A>C p.E132D | Missense Mutation (SNP) | VAF 25/271 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.606); called by muse, mutect2
- CENPF | c.7352A>T p.N2451I | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2
- FAM186B | c.167T>C p.L56S | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.198); called by muse, mutect2
- HSPD1 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 20/614 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.172); called by muse, mutect2
- INPP5K | c.1051T>C p.S351P | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- ISL2 | c.14T>G p.I5S | Missense Mutation (SNP) | VAF 58/600 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- LYRM1 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 42/371 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.478); called by muse, mutect2
- NRG3 | c.953+2T>C p.X318_splice | Splice Site (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- SMURF1 | c.1820T>C p.L607P | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SULT1C2 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TALDO1 | c.837C>A p.A279= | Splice Region (SNP) | VAF 39/566 reads (7%) | called by muse, mutect2
- TNPO1 | c.463-2A>G p.X155_splice | Splice Site (SNP) | VAF 26/232 reads (11%) | called by muse, mutect2, varscan2
- UTP4 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 46/450 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- DYSF | c.2223C>T p.Y741= | Silent (SNP) | VAF 32/402 reads (8%) | catalogued as rs200188905; called by muse, mutect2
- HOXD8 | c.339G>A p.P113= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- NCKIPSD | c.1338C>G p.A446= | Silent (SNP) | VAF 32/251 reads (13%) | called by muse, mutect2, varscan2
- RNF223 | c.705C>T p.A235= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2
- TRPM3 | c.1803C>T p.F601= (on ENST00000357533 / NM_001366142.2; = p.F434= on NM_020952.6) | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV62585223; called by muse, mutect2, varscan2
- TTPA | c.276T>C p.I92= | Silent (SNP) | VAF 37/357 reads (10%) | called by muse, mutect2, varscan2
- ZNF407 | c.5688C>T p.A1896= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs373977862; called by muse, mutect2, varscan2
- MGAM | c.4619-12073C>T | Intron (SNP) | VAF 22/383 reads (6%) | catalogued as rs1429316496; called by muse, mutect2
- RNF216 | c.202-26A>G | Intron (SNP) | VAF 32/466 reads (7%) | called by muse, mutect2
